Gene-level copy-number profile of tumor specimen C3L-04331-01 from CPTAC case C3L-04331, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 87.7 years (32,040 days).
Specimen C3L-04331-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e6fd8a3-ce6b-474b-adb3-8453d2526099.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04331-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/e55cecb4-cfe6-4472-9afc-8d39c69c8c1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 235; copy number 1: 19,273; copy number 2: 37,850; copy number 3: 1,488; copy number 4: 52; copy number 5: 2; copy number 6: 2; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 235 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,003,106–22,552,156, 104 genes (broad region; genes not listed).
- chr14:105,639,559–105,644,790, 1 gene (within-gene range 0–1): IGHG2.
- chr14:105,647,924–106,481,706, 128 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 23: RPL23AP88.
- chr5:126,737,438–126,737,995, 1 gene, copy number 5: HSPE1P10.
- chr13:112,313,467–112,331,225, 2 genes, copy number 6: LINC01043, LINC01044.
- chr21:46,690,764–46,691,226, 1 gene, copy number 5: RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 16,417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
